Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A7X8, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A7X8-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT - CONSULT

Patient Name: [REDACTED]
Address: [REDACTED] Service: [REDACTED] Accession #: [REDACTED]
Gender: F Location: [REDACTED] Received: [REDACTED]
DOB: [REDACTED] (Age: [REDACTED]) MRN: [REDACTED] Reported: [REDACTED]
Hospital #: [REDACTED]
Patient Type: [REDACTED]
Physician(s): [REDACTED] M.D.

DIAGNOSIS

- UTERUS, CERVIX, SUPERIOR, BIOPSY [REDACTED]
- INVASIVE MUCINOUS ADENOCARCINOMA, ENDOCERVICAL TYPE, EXTENSIVELY INVOLVING CAUTERIZED MARGINS (SEE COMMENT)
- SQUAMOUS EPITHELIUM WITH ACUTE AND CHRONIC INFLAMMATION
- UTERUS, CERVIX, INFERIOR, BIOPSY [REDACTED]
- INVASIVE MUCINOUS ADENOCARCINOMA, ENDOCERVICAL TYPE, EXTENSIVELY INVOLVING CAUTERIZED MARGINS
- UTERUS, ENDOCERVIX, "ENDOCERVICAL CANAL," BIOPSY [REDACTED]
- ABUNDANT DETACHED FRAGMENTS OF MUCINOUS ADENOCARCINOMA

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

[REDACTED] M.D.

Report Electronically Reviewed and Signed Out By [REDACTED] M.D.

Microscopic Description and Comment

Histologic sections from both superior and inferior cervical biopsies show invasive adenocarcinoma, moderately differentiated. The morphologic features are distorted in much of these specimens by extensive cautery effect. Where relatively well preserved, the tumor invades as large nests of moderately pleomorphic cells with abundant mucinous cytoplasm and a high mitotic rate. This tumor is best classified as mucinous adenocarcinoma of endocervical type, although many of the cells have signet ring features and there are small foci of endometrioid differentiation as well. Tumor is present on virtually every section from these large biopsies and is present at multiple inked and cauterized margins. Detached fragments of adenocarcinoma are present in the endocervical canal biopsy.

History

The patient is a [REDACTED] year old woman with cervical cancer.

[REDACTED] Ph.D.

ICD O-3

Adenocarcinoma, mucinous
endocervical type 8482/3

Site Cervix NOS C53.9

9/10/10/13

[page 2 of 2]
Material(s) Received

Received are 15 slides labeled [REDACTED]. Three are not further sub-labeled, three are sub-labeled A2, three are sub-labeled B1, three are sub-labeled B2 and three are sub-labeled C1. These are derived from a superior cervix biopsy (A), inferior cervix biopsy (B), and endocervical canal biopsy (C) [REDACTED] in the accompanying corresponding pathology report. The material originates from [REDACTED]

Physician Copy
END OF REPORT

Page 2 of 2

Source: NCI Genomic Data Commons file ac55afd1-a3bb-4acd-b591-6d0d1fc2cb4e (TCGA-C5-A7X8.06979EDA-C06B-46E7-A4B0-C20D1E340F4B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).